CGCI case BLGSP-71-22-00330 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/765a8f7f-9cdb-4b3f-8024-0eb777a34c4b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 9 years; Vital status: Dead; Days to death: 16 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 9.2 years (3,375 days); Year of diagnosis: 2014; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Bone marrow / Peritoneum, NOS / Gallbladder / Liver / Small intestine / Ovary, NOS / Lung, NOS / Pleura.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Femoral; Tumor largest dimension diameter: 5 cm.
   Pathology details: Lymph node involved site: Inguinal.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ANHL1131- only received prophase of cyclosphosphamide, Vincristine and prednisone; Days to treatment start: 0 days; Days to treatment end: 3 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Days to treatment end: 3 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 0 days; Karnofsky performance status: 50.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 2342 [Blood test normal range upper: 234].

Other clinical attributes
- Day 0: Weight: 49 kg; Height: 148 cm; BMI: 22.4.

Biospecimens (2 samples)
- Sample BLGSP-71-22-00330-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: FFPE; Days to sample procurement: 0 days; Tissue collection type: Prospective.
- Sample BLGSP-71-22-00330-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Cause of death: Non-Cancer Related; History neoadjuvant treatment: No; Lost to follow-up: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone Marrow; Extranodal involvement site: Ascites/Peritoneum; Extranodal involvement site: Gallbladder; Extranodal involvement site: Liver; Extranodal involvement site: Small Intestine; Extranodal involvement site: Ovary; Extranodal involvement site: Lung; Extranodal involvement site: Pleura/Pleural Effusion.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 2342; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify).
